Somatic mutation profile of tumor specimen TARGET-10-PARLJA-09A (aliquot TARGET-10-PARLJA-09A-01D) from TARGET case TARGET-10-PARLJA, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.6 years (3,151 days).
Specimen TARGET-10-PARLJA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60de7225-5c9f-41b4-9d13-1530bfe3bcd5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARLJA-14A (Bone Marrow Normal), aliquot TARGET-10-PARLJA-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eba86fe7-114e-44cf-a654-b0cd15c292f1

The open-access MAF lists 30 somatic variants for this specimen: 20 protein-altering or splice-affecting, 3 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Intron 4, Silent 3, 3'UTR 2, In Frame Ins 2, Frame Shift Del 1, Nonsense Mutation 1, 3'Flank 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS12 | c.1661G>A p.C554Y | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61258369; called by muse, mutect2, varscan2
- FCAR | c.200C>T p.T67M | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs1227385567, COSV62028933; called by muse, mutect2, varscan2
- GAK | c.2398G>A p.E800K | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.103); catalogued as rs151239768; called by muse, mutect2, varscan2
- LGI1 | c.1090G>A p.G364R | Missense Mutation (SNP) | VAF 27/254 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV65057601; called by muse, mutect2
- LRRN2 | c.784G>A p.G262R | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs868643108, COSV65783409; called by muse, mutect2
- MAGI1 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.956); catalogued as rs376397867, COSV58314242; called by muse, mutect2, varscan2
- MYOF | c.4503C>G p.F1501L | Missense Mutation (SNP) | VAF 110/253 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV63701258, COSV63701823; called by muse, mutect2, varscan2
- NPC1L1 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs199897840; called by muse, mutect2, varscan2
- OR52I2 | c.19C>T p.R7W | Missense Mutation (SNP) | VAF 65/220 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs200571706, COSV100442840; called by muse, mutect2, varscan2
- PCP2 | c.54G>A p.A18= | Splice Region (SNP) | VAF 35/87 reads (40%) | catalogued as rs144058203; called by muse, mutect2, varscan2
- PRH1 | c.238C>T p.Q80* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as COSV70371816; called by muse, mutect2, varscan2
- SUPT3H | c.908G>A p.R303H (on ENST00000371460 / NM_181356.3; = p.R292H on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs776630523, COSV60935832; called by muse, mutect2, varscan2
- TRIM36 | c.98G>T p.C33F | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56688869; called by muse, mutect2
- TRMT10C | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.099); catalogued as COSV59305338; called by muse, mutect2, varscan2
- ZIC5 | c.1816G>T p.A606S | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs761850472, COSV57437098; called by muse, mutect2, varscan2
- ZNF341 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs759711668, COSV61007279; called by muse, mutect2, varscan2
- FAM120B | c.849del p.K283Nfs*2 | Frame Shift Del (DEL) | VAF 41/131 reads (31%) | called by mutect2, pindel, varscan2
- TRAV3 | c.343delinsGAGCCTAG | In Frame Ins (INS) | VAF 34/44 reads (77%) | called by pindel, varscan2*
- TRAV5 | c.339_340insTACC | In Frame Ins (INS) | VAF 36/46 reads (78%) | called by mutect2, pindel*, varscan2
- UPB1 | c.206_207insTCCCGACC p.R70Pfs*34 | Frame Shift Ins (INS) | VAF 24/63 reads (38%) | called by mutect2, pindel, varscan2
- SEMA3D | c.543G>T p.L181= | Silent (SNP) | VAF 16/125 reads (13%) | catalogued as COSV52390940; called by muse, mutect2, varscan2
- SLC7A4 | c.660C>T p.H220= | Silent (SNP) | VAF 9/116 reads (8%) | called by muse, mutect2
- UNC45B | c.2671C>T p.L891= | Silent (SNP) | VAF 46/77 reads (60%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.7474-47G>A | Intron (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- EPHB1 | c.805+26023C>T | Intron (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2, varscan2
- HBD | c.-29+265C>T | Intron (SNP) | VAF 32/84 reads (38%) | catalogued as rs570039679; called by muse, mutect2, varscan2
- IGHV1-45 | chr14:106506995 ins GGAGAAAGGA | 3'Flank (INS) | VAF 28/80 reads (35%) | called by mutect2, pindel, varscan2
- IGSF5 | c.957-54T>C | Intron (SNP) | VAF 13/28 reads (46%) | called by muse, mutect2
- KRT24 | c.*9C>A | 3'UTR (SNP) | VAF 19/209 reads (9%) | called by muse, mutect2
- TIRAP | c.*795G>A | 3'UTR (SNP) | VAF 39/77 reads (51%) | called by muse, mutect2, varscan2
